Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHE, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAHE-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 7.0 cm; tumor is present in the rete testis; the tunica albuginea is not penetrated. Tumor extends close to the epididymis but does not penetrate it. The cord is not involved, including the resection margin..

Date of procurement (= date of orchidectomy):

ICD-O 3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
yo 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 6479f33c-0983-4d22-821f-fc144a93b45c (TCGA-2G-AAHE-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).